Somatic mutation profile of tumor specimen ALCH-B2FA-TTP1-A (aliquot ALCH-B2FA-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2FA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.6 years (20,311 days).
Specimen ALCH-B2FA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79e8aa5d-f7fc-4ffa-a76a-3eaf0c268b7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FA-NB1-A (Blood Derived Normal), aliquot ALCH-B2FA-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1568475a-bcdf-4adf-9d32-29ea09295d4d

The open-access MAF lists 1,347 somatic variants for this specimen: 950 protein-altering or splice-affecting, 248 silent, 149 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 811, Silent 248, Nonsense Mutation 67, Intron 59, RNA 33, Splice Site 31, Frame Shift Del 24, 3'UTR 21, 5'Flank 14, 5'UTR 14, Splice Region 8, 3'Flank 8.

Variants (750 of 1,347; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 75/431 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- RP1L1 | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as rs756996764, COSV66755966; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3204G>A p.M1068I | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs762424228; called by muse, mutect2, varscan2
- AC100868.1 | c.1561G>T p.G521* | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | catalogued as COSV51837967; called by muse, mutect2, varscan2
- ACADM | c.347G>C p.C116S | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM970024, COSV63721081; called by muse, mutect2, varscan2
- ACTL7B | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65927155; called by muse, mutect2, varscan2
- ADAMTS2 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as rs752381136; called by muse, mutect2, varscan2
- ADAMTS5 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424626157, COSV99537574; called by muse, mutect2, varscan2
- ADCY8 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs774800014, COSV53914076; called by muse, varscan2
- ADGRA1 | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV66926478; called by muse, mutect2, varscan2
- ADGRG4 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV54949340; called by muse, mutect2
- ADGRL2 | c.2942+1G>T p.X981_splice (on ENST00000370717 / NM_001366005.1; = p.X968_splice on NM_012302.4) | Splice Site (SNP) | VAF 9/91 reads (10%) | catalogued as COSV54674289; called by muse, mutect2, varscan2
- ADGRL3 | c.2816C>G p.A939G (on ENST00000506720 / NM_001322402.2; = p.A871G on NM_015236.6) | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101546801, COSV72230433; called by muse, mutect2
- ADK | c.233A>G p.H78R (on ENST00000286621; = p.H61R on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/471 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1424296143; called by muse, mutect2
- ALG13 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52645824; called by muse, mutect2
- ANHX | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470303184; called by muse, mutect2, varscan2
- ANKK1 | c.804G>C p.W268C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs901716735, COSV58270969; called by muse, mutect2, varscan2
- ANXA1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV57410908; called by muse, mutect2
- ANXA6 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.314); catalogued as COSV62908255; called by muse, mutect2, varscan2
- AP002512.3 | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as COSV54406583; called by muse, mutect2, varscan2
- APOBEC3G | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 15/158 reads (9%) | catalogued as COSV68470341; called by muse, mutect2, varscan2
- AR | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421832550, COSV65964685; called by muse, mutect2, varscan2
- ARAP1 | c.1384G>A p.G462R (on ENST00000393609 / NM_001040118.2; = p.G217R on NM_015242.4) | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs768253842, COSV61996051; called by muse, mutect2, varscan2
- ARHGAP32 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59850454; called by muse, mutect2, varscan2
- ARHGAP33 | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV50159225; called by muse, mutect2, varscan2
- ARPP21 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV99491071; called by muse, mutect2, varscan2
- ATP8B2 | c.3019G>T p.G1007W (on ENST00000672630; = p.G974W on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV100528285; called by muse, mutect2, varscan2
- ATP8B4 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52725409; called by muse, mutect2, varscan2
- ATR | c.4000C>T p.Q1334* | Nonsense Mutation (SNP) | VAF 33/224 reads (15%) | catalogued as COSV63386314, COSV63388597; called by muse, mutect2, varscan2
- BBOX1 | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 32/278 reads (12%) | catalogued as rs985315416, COSV54189551; called by muse, varscan2
- BCR | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.061); catalogued as COSV100006093; called by muse, mutect2
- BICRA | c.2797G>T p.A933S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.025); catalogued as rs868626276; called by muse, mutect2
- BRWD3 | c.1283T>A p.M428K | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100955982; called by muse, mutect2
- BTBD17 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100945206; called by muse, mutect2, varscan2
- C1QTNF9B | c.167-1G>A p.X56_splice | Splice Site (SNP) | VAF 17/111 reads (15%) | catalogued as rs1252288782; called by muse, mutect2, varscan2
- C4orf50 | c.142C>A p.R48S (on ENST00000324058; = p.R1280S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.253); catalogued as rs768362868, COSV100135828; called by muse, mutect2, varscan2
- CA10 | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780641204, COSV53353383; called by muse, mutect2
- CABS1 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1301821681, COSV56732873; called by muse, varscan2
- CACNA1A | c.2267C>A p.S756Y | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs535900273; called by muse, mutect2, varscan2
- CACNA1A | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64192782; called by muse, mutect2, varscan2
- CAPN13 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV54436519, COSV99039073; called by muse, mutect2, varscan2
- CASZ1 | c.3263C>A p.P1088Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs538567404, COSV59732185; called by muse, mutect2, varscan2
- CCDC27 | c.1322G>C p.G441A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53902690; called by muse, mutect2
- CCNB3 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as rs1189103204; called by muse, mutect2
- CD1D | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV63809134; called by muse, mutect2
- CD6 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100533017; called by muse, mutect2, varscan2
- CD99L2 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.185); catalogued as COSV100692235; called by muse, mutect2
- CDCA2 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303439712, COSV55341983; called by muse, varscan2
- CDH26 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV99722511; called by muse, mutect2, varscan2
- CDH7 | c.2005G>T p.A669S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.315); catalogued as COSV59882275; called by muse, mutect2, varscan2
- CDH8 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54844928; called by muse, mutect2, varscan2
- CELF1 | c.1004-1G>A p.X335_splice (on ENST00000358597 / NM_001376422.1; = p.X331_splice on NM_006560.4 and 10 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as COSV60116809; called by muse, mutect2
- CHD7 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.184); catalogued as COSV71109079; called by muse, mutect2, varscan2
- CHD8 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs1352806894; called by muse, mutect2, varscan2
- CHRNA4 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV64719770; called by muse, mutect2
- CHRNB2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs1286054801; ClinVar: uncertain significance; called by muse, mutect2
- COL11A1 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs745563977; called by muse, mutect2, varscan2
- COL14A1 | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 62/565 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776711515; called by muse, mutect2, varscan2
- COL3A1 | c.2296C>A p.P766T | Missense Mutation (SNP) | VAF 54/478 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV58597358; called by muse, mutect2, varscan2
- COL5A2 | c.907-1G>T p.X303_splice | Splice Site (SNP) | VAF 44/291 reads (15%) | catalogued as COSV66409315; called by muse, mutect2, varscan2
- COL5A3 | c.4058G>T p.R1353L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as rs771836964, COSV53406165, COSV53413860; called by muse, mutect2, varscan2
- COL6A5 | c.4420del p.E1474Kfs*10 | Frame Shift Del (DEL) | VAF 35/212 reads (17%) | catalogued as COSV55215061; called by mutect2, pindel, varscan2
- CRYBA4 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1055687824; called by muse, mutect2, varscan2
- CRYZ | c.388G>C p.G130R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV61717610; called by muse, mutect2, varscan2
- CSMD2 | c.8651C>A p.S2884* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV53891186; called by muse, mutect2, varscan2
- CT47B1 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs200243472, COSV64890855; called by muse, mutect2
- CXorf66 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV65169564; called by muse, mutect2, varscan2
- CYP11B1 | c.1361del p.R454Pfs*15 | Frame Shift Del (DEL) | VAF 32/193 reads (17%) | catalogued as CM1515479; called by mutect2, pindel*, varscan2
- CYP2F1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777323567; called by muse, mutect2, varscan2
- DBH | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV67549981; called by muse, mutect2, varscan2
- DCAF12L1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV64421480; called by muse, mutect2
- DCAF8L2 | c.1439C>A p.P480H | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101446216; called by muse, mutect2
- DCC | c.2882G>T p.R961L | Missense Mutation (SNP) | VAF 45/481 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100501723; called by muse, mutect2
- DISP1 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as COSV52659797; called by muse, mutect2, varscan2
- DMBX1 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63601891; called by muse, mutect2, varscan2
- DMD | c.10625C>G p.P3542R | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD132430; called by muse, mutect2
- DMD | c.1394C>A p.T465K | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as CD073614; called by muse, mutect2
- DMP1 | c.1215C>G p.D405E | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.619); catalogued as rs907677714; called by muse, varscan2
- DNAH1 | c.2429C>T p.T810I | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1378519445; called by muse, mutect2
- DNAH10 | c.1136C>T p.A379V (on ENST00000409039; = p.A318V on NM_207437.3) | Missense Mutation (SNP) | VAF 51/444 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101292128; called by muse, mutect2, varscan2
- DNAH3 | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1286389645, COSV54500770; called by muse, mutect2, varscan2
- DSG1 | c.335C>A p.T112K | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99936544; called by muse, mutect2, varscan2
- DTWD1 | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV52073126; called by muse, mutect2, varscan2
- ENPP7 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555822966; called by muse, mutect2, varscan2
- EPB42 | c.1009C>A p.P337T (on ENST00000441366 / NM_001114134.2; = p.P367T on NM_000119.3) | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV55751255; called by muse, mutect2, varscan2
- EPN2 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs903112841; called by muse, mutect2, varscan2
- ERBB4 | c.3799T>A p.F1267I | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV61517981; called by muse, mutect2, varscan2
- ERV3-1 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51427018; called by muse, mutect2, varscan2
- F8 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD055673, CM081249; called by muse, mutect2
- FAM104A | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs781642632; called by muse, mutect2, varscan2
- FAM135B | c.1753T>A p.Y585N | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99424277; called by muse, mutect2, varscan2
- FAM71A | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99674653; called by muse, mutect2, varscan2
- FANCB | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV60759626; called by muse, mutect2
- FCAR | c.597G>C p.R199S | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV62031255, COSV62031585; called by muse, mutect2, varscan2
- FLNC | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1274480597; called by muse, mutect2, varscan2
- FOXN4 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100142061; called by muse, varscan2
- FPR2 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV60673394; called by muse, mutect2, varscan2
- FSCB | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as COSV61218583; called by muse, mutect2, varscan2
- FSTL5 | c.2143C>A p.L715I | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV60207655; called by muse, mutect2
- GALNT14 | c.1460C>A p.P487Q | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV61102746; called by muse, mutect2, varscan2
- GLRA1 | c.797C>A p.S266* | Nonsense Mutation (SNP) | VAF 62/381 reads (16%) | catalogued as COSV99199674; called by muse, mutect2, varscan2
- GPR61 | c.457C>A p.R153S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV68177920; called by muse, mutect2, varscan2
- GPR85 | c.891G>T p.L297F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs1004492133; called by muse, mutect2, varscan2
- GRB14 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.02); catalogued as COSV55736644; called by muse, mutect2
- GRIK5 | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53478085; called by muse, mutect2
- GTF2E1 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52205074; called by muse, mutect2
- GUCY1A2 | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV56478233; called by muse, mutect2, varscan2
- HAND1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.798); catalogued as COSV50562605; called by muse, mutect2, varscan2
- HAPLN1 | c.992C>A p.A331E | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99165258; called by muse, mutect2, varscan2
- HMGN5 | c.669del p.D225Mfs*2 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | catalogued as rs1206962734; called by mutect2, pindel*, varscan2
- HNRNPUL2 | c.989A>G p.D330G | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs745522368; called by muse, mutect2, varscan2
- IGF2 | c.500G>T p.G167V (on ENST00000434045 / NM_001127598.3; = p.G111V on NM_000612.6) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as rs745901132; called by muse, mutect2, varscan2
- IGHV1-46 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1555524656; called by muse, mutect2
- IGHV3-11 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782601313; called by muse, varscan2
- IGSF5 | c.515del p.P172Rfs*29 | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | catalogued as COSV101012138; called by mutect2, pindel
- IL31RA | c.2087C>A p.P696Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV61693870; called by muse, mutect2, varscan2
- IPO5 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.063); catalogued as rs1251457064; called by muse, mutect2
- IQGAP1 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV51582074; called by muse, mutect2
- ISX | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58085991; called by muse, mutect2, varscan2
- ITPR1 | c.6703G>A p.E2235K (on ENST00000354582; = p.E2180K on NM_002222.7) | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV56987052; called by muse, mutect2
- KCNJ12 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782625440, COSV59172867; called by muse, mutect2, varscan2
- KEL | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as rs777488665; called by muse, mutect2, varscan2
- KIR3DL1 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100428809; called by muse, mutect2
- KLK14 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as rs770591913; called by muse, mutect2, varscan2
- KRT83 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV53342100; called by muse, mutect2, varscan2
- KRTAP19-5 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 33/385 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV61858437, COSV61859736; called by muse, mutect2
- LAMB1 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758179734; called by muse, mutect2, varscan2
- LCE5A | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.693); catalogued as COSV57500059; called by muse, mutect2, varscan2
- LIPC | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.403); catalogued as COSV54424433; called by muse, mutect2, varscan2
- LIPK | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV68201474; called by muse, mutect2
- LPAR4 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.51); catalogued as COSV70913115, COSV70913491; called by muse, mutect2
- LRRIQ3 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs758821601; called by muse, mutect2, varscan2
- MAGEB16 | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV101303262; called by muse, mutect2
- MAGEB6 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.33); catalogued as COSV66872000; called by muse, mutect2
- MAGED2 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV54498034; called by muse, mutect2
- MAST1 | c.2036del p.S679* | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as COSV52241619; called by pindel, varscan2
- MBD1 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM055980; called by muse, mutect2, varscan2
- MFSD3 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56743561; called by muse, mutect2, varscan2
- MGA | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 31/226 reads (14%) | catalogued as COSV54951116; called by muse, mutect2, varscan2
- MGAM | c.4360G>T p.D1454Y | Missense Mutation (SNP) | VAF 54/423 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV72075070; called by muse, mutect2, varscan2
- MKRN3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58812275; called by muse, mutect2, varscan2
- MRPS18C | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55025730; called by muse, mutect2
- MTM1 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV60334490; called by muse, mutect2, varscan2
- MUC16 | c.28416G>T p.M9472I | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as COSV67475705; called by muse, mutect2, varscan2
- MYLK3 | c.1433C>A p.P478Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as COSV67363894; called by muse, mutect2, varscan2
- NCAM1 | c.2133C>A p.A711= (on ENST00000316851 / NM_181351.5; = p.A701= on NM_000615.7) | Splice Region (SNP) | VAF 11/108 reads (10%) | catalogued as COSV57526967; called by muse, mutect2
- NCF1 | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs1437749725; called by mutect2, varscan2
- NEB | c.9460G>T p.V3154F | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV50806214, COSV50814958, COSV99425534; called by muse, mutect2, varscan2
- NID1 | c.1781C>A p.P594H | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51629598; called by muse, mutect2, varscan2
- NLRP14 | c.3269G>T p.W1090L | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs760864688; called by muse, mutect2, varscan2
- NLRP7 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 56/406 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.514); catalogued as rs930949107, COSV100051438; called by muse, mutect2, varscan2
- NMUR2 | c.783del p.C262Afs*14 | Frame Shift Del (DEL) | VAF 24/206 reads (12%) | catalogued as COSV54919733; called by mutect2, pindel, varscan2
- NOS1 | c.3266G>T p.R1089L | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57613331; called by muse, mutect2, varscan2
- NOS1 | c.1303C>A p.R435S | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57612231; called by muse, mutect2, varscan2
- NPAP1 | c.1010C>G p.P337R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61508177, COSV61513035; called by muse, mutect2, varscan2
- NPHS2 | c.379-2A>G p.X127_splice | Splice Site (SNP) | VAF 66/287 reads (23%) | catalogued as CS156483; called by muse, mutect2, varscan2
- NTRK3 | c.505C>A p.R169S | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.669); catalogued as COSV100447378; called by muse, mutect2, varscan2
- NYNRIN | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs779532173; called by muse, mutect2, varscan2
- OGDHL | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65100813; called by muse, mutect2, varscan2
- OLFM1 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV52962358; called by muse, mutect2, varscan2
- OR10G7 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57866579; called by muse, mutect2, varscan2
- OR10W1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs1415796756, COSV99063476; called by muse, mutect2, varscan2
- OR2L13 | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs758894902, COSV63548767, COSV63552854; called by muse, mutect2, varscan2
- OR2T4 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 51/619 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100822664, COSV63544279; called by muse, mutect2
- OR2T6 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63216899; called by muse, mutect2
- OR4A16 | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.378); catalogued as COSV59043183; called by muse, mutect2, varscan2
- OR4C13 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV73648683; called by muse, mutect2, varscan2
- OR56B4 | c.801C>A p.H267Q | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs765306002, COSV57205409; called by muse, mutect2, varscan2
- OR8H1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57294161; called by mutect2, varscan2
- OTOG | c.5795C>A p.P1932H | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs1191107652; called by muse, mutect2, varscan2
- PBRM1 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 29/221 reads (13%) | catalogued as COSV56301506; called by muse, mutect2, varscan2
- PCDHA1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV65377629; called by muse, mutect2, varscan2
- PCDHB12 | c.1613C>A p.S538Y | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs781856090, COSV53396490; called by muse, varscan2
- PCDHGA6 | c.2205G>T p.M735I | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs753554580; called by muse, mutect2, varscan2
- PCDHGB7 | c.384C>A p.D128E | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54000140; called by muse, mutect2
- PCDHGB7 | c.385C>G p.H129D | Missense Mutation (SNP) | VAF 33/399 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs746986702, COSV54063757; called by muse, mutect2
- PDCD1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs200312345, COSV57691913; called by muse, mutect2, varscan2
- PHKA2 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs373884791; called by muse, mutect2, varscan2
- PHOSPHO1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs749076783; called by muse, mutect2
- PI15 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52639690; called by muse, mutect2, varscan2
- PKD1 | c.5251A>T p.T1751S | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs753878434; called by muse, mutect2, varscan2
- PLCB1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs751256923, COSV62039592; called by muse, mutect2
- PLCB1 | c.2778C>G p.H926Q | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs138373296; called by muse, mutect2, varscan2
- PLCL1 | c.2069del p.G690Dfs*6 | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | catalogued as COSV70830591; called by mutect2, varscan2
- PLEKHA7 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs997758563, COSV100850243; called by muse, mutect2, varscan2
- PLXNB3 | c.4046del p.P1349Rfs*62 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs1557063545; called by mutect2, pindel, varscan2
- POTEE | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 30/487 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); catalogued as rs1443877295, COSV58228042; called by muse, mutect2
- PPFIA4 | c.2320C>T p.R774W (on ENST00000447715; = p.R775W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs749614169; called by muse, mutect2, varscan2
- PPP1R37 | c.1997T>C p.L666P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1435233668; called by muse, mutect2, varscan2
- PRDM16 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373162966; called by muse, mutect2, varscan2
- PRDM9 | c.2383C>A p.Q795K | Missense Mutation (SNP) | VAF 60/526 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV57005843; called by muse, varscan2
- PRDX3 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1312661655; called by muse, mutect2, varscan2
- PRR23B | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100272146, COSV61493913; called by muse, mutect2
- PSME4 | c.3781A>G p.K1261E | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550418250; called by muse, mutect2
- PSME4 | c.812A>G p.D271G | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs757753980; called by muse, mutect2, varscan2
- PTH1R | c.207G>C p.W69C | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as rs557755099; called by muse, mutect2
- QDPR | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1210367, CM920601, COSV55549744; called by muse, mutect2, varscan2
- RAB40AL | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505035; called by muse, mutect2
- RAD54L2 | c.3430G>T p.E1144* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV56577385, COSV99620734; called by muse, mutect2
- REG3A | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as COSV59408599; called by muse, mutect2, varscan2
- RET | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV60704091; called by muse, mutect2, varscan2
- RET | c.2393G>T p.G798V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60699356; called by muse, mutect2
- RIBC1 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV51448441; called by muse, mutect2
- ROBO3 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs745483542, COSV67299485; called by muse, mutect2, varscan2
- RP1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55127483; called by muse, mutect2
- RTCA | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.142); catalogued as COSV53119369; called by muse, mutect2, varscan2
- RTL3 | c.1262C>A p.P421H | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs1436186561, COSV100329558, COSV58183723; called by muse, mutect2
- RTL3 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1186448900, COSV58186146; called by muse, varscan2
- RYR1 | c.12839C>T p.A4280V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1433605446; called by muse, mutect2
- RYR3 | c.11192C>T p.T3731M (on ENST00000389232; = p.T3732M on NM_001036.6) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866654080; called by muse, mutect2, varscan2
- SCN3A | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51802729; called by muse, mutect2, varscan2
- SCN3B | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs765104250, COSV54798251; called by muse, mutect2, varscan2
- SCN7A | c.3068T>A p.L1023Q | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV69273398; called by muse, mutect2
- SEMA5A | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 23/369 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453974287, COSV66790356; called by muse, mutect2
- SEPHS2 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72100771; called by muse, mutect2, varscan2
- SHTN1 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as rs913008132, COSV53384650; called by muse, mutect2, varscan2
- SI | c.1146+1G>A p.X382_splice | Splice Site (SNP) | VAF 56/328 reads (17%) | catalogued as rs776450537, COSV100015907; called by muse, mutect2, varscan2
- SLC12A3 | c.1103C>A p.A368D | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as COSV99343692; called by muse, varscan2
- SLC12A5 | c.2852G>C p.R951P (on ENST00000454036 / NM_001134771.2; = p.R928P on NM_020708.5) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV54796008; called by muse, mutect2, varscan2
- SLC18A2 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as COSV53688749; called by muse, mutect2
- SLC22A25 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); catalogued as rs1441706259; called by muse, mutect2, varscan2
- SLFN11 | c.2613G>T p.R871S | Missense Mutation (SNP) | VAF 91/378 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV100390696; called by muse, mutect2, varscan2
- SLITRK2 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59427147; called by muse, mutect2, varscan2
- SMO | c.1444C>A p.R482S | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.826); catalogued as rs755295928, COSV50825724; called by muse, mutect2, varscan2
- SNX13 | c.2426A>G p.Y809C | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1320674041; called by muse, mutect2, varscan2
- SPATA48 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs773612283; called by muse, mutect2, varscan2
- SPTA1 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 64/572 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV63751930; called by muse, mutect2, varscan2
- SPTBN2 | c.4503+1G>A p.X1501_splice | Splice Site (SNP) | VAF 21/142 reads (15%) | catalogued as rs759362790; called by muse, mutect2, varscan2
- SSH2 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52174023; called by muse, mutect2, varscan2
- SSTR3 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs202229747, COSV100142636; called by muse, mutect2, varscan2
- SULT2A1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs758752472; called by muse, mutect2
- SYTL4 | c.1999C>A p.Q667K | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1379344429; called by muse, mutect2
- TACC2 | c.7234G>A p.G2412R (on ENST00000334433; = p.G490R on NM_006997.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs768585905; called by muse, mutect2, varscan2
- TAFA4 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55140798; called by muse, mutect2, varscan2
- TBC1D24 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760666914, COSV53547767; called by muse, mutect2, varscan2
- TENM3 | c.2693G>T p.R898L | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69308393; called by muse, mutect2, varscan2
- TEP1 | c.5920G>T p.A1974S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.662); catalogued as rs752099970, COSV52988568; called by muse, mutect2, varscan2
- TIGIT | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV67329162; called by muse, mutect2
- TJP2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.303); catalogued as rs1232075308; called by muse, mutect2, varscan2
- TMEM131L | c.4772C>T p.A1591V | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199553865, COSV53643112; called by muse, mutect2
- TMEM151B | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs1360249220; called by muse, mutect2
- TNR | c.1671C>A p.S557R | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs764419247; called by muse, mutect2
- TNR | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54914766; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 43/217 reads (20%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TP53BP1 | c.3600G>T p.R1200S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1489937923; called by muse, mutect2, varscan2
- TPCN2 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879476129; called by muse, varscan2
- TRANK1 | c.4999G>T p.A1667S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs761438132, COSV57147337; called by muse, mutect2
- TRIM51GP | c.762-1G>A p.X254_splice | Splice Site (SNP) | VAF 35/279 reads (13%) | catalogued as rs1311754695; called by muse, mutect2, varscan2
- TRIM67 | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 20/159 reads (13%) | catalogued as COSV64159192; called by muse, varscan2
- TRIM67 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64158938; called by muse, varscan2
- TRIML1 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs113311676, COSV60197274; called by muse, varscan2
- TRPC3 | c.785C>G p.P262R (on ENST00000379645 / NM_001366479.2; = p.P189R on NM_003305.2) | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53377224; called by muse, mutect2, varscan2
- TTBK1 | c.1382G>T p.R461M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99444825; called by muse, mutect2, varscan2
- UACA | c.1768C>G p.R590G | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV59855368; called by muse, mutect2, varscan2
- UGT1A5 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs376312935; called by muse, mutect2, varscan2
- UNC13A | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs752332782, COSV53189661; called by muse, mutect2, varscan2
- URGCP | c.1477G>T p.E493* (on ENST00000453200 / NM_001077663.3; = p.E484* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 41/273 reads (15%) | catalogued as COSV56251017; called by muse, mutect2, varscan2
- USH2A | c.9258G>T p.Q3086H | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380261595, CM165980; ClinVar: uncertain significance; called by muse, mutect2
- USH2A | c.1589C>G p.T530R | Missense Mutation (SNP) | VAF 65/449 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs76458883; called by muse, mutect2, varscan2
- VN1R2 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV59037188, COSV59038201; called by muse, mutect2, varscan2
- VWA5A | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100795690; called by muse, mutect2, varscan2
- WASF3 | c.1369G>T p.V457L | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58970604; called by mutect2, varscan2
- WASHC5 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as rs541330058, COSV59195722; called by muse, mutect2, varscan2
- XK | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66120175; called by muse, mutect2
- ZEB2 | c.2329C>A p.H777N | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.549); catalogued as rs587784564; called by muse, mutect2, varscan2
- ZFHX4 | c.2336C>G p.A779G | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV50924910, COSV51486460, COSV99266984; called by muse, mutect2, varscan2
- ZFHX4 | c.6988C>A p.H2330N | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99263787; called by muse, mutect2, varscan2
- ZFP82 | c.1211G>T p.S404I | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.196); catalogued as COSV101089185; called by muse, mutect2, varscan2
- ZNF469 | c.7412C>A p.P2471Q (on ENST00000437464; = p.P2499Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs1015197481; called by muse, mutect2, varscan2
- ZNF536 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV100834512; called by muse, mutect2, varscan2
- ZNF804A | c.3454G>T p.G1152* | Nonsense Mutation (SNP) | VAF 21/228 reads (9%) | catalogued as COSV56439275; called by muse, mutect2
- ZNF804A | c.3455G>T p.G1152V | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56456687; called by muse, mutect2
- ZNF835 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73379402; called by muse, mutect2, varscan2
- ZNF85 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV56021386; called by muse, mutect2, varscan2
- AADAT | c.1083A>T p.K361N | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- AASDH | c.2586G>T p.M862I | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2
- ABCA13 | c.6297G>C p.L2099F | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ABCA13 | c.7808G>T p.G2603V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ABCF3 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ABHD16B | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABI3 | c.867del p.L290Cfs*25 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel*, varscan2
- ACACB | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- ACTN2 | c.1563T>A p.F521L | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ACTN2 | c.2060A>T p.N687I | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ADAM22 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2
- ADAM8 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ADAMTS12 | c.1635G>T p.W545C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADAMTS13 | c.1339T>A p.S447T | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS17 | c.3053C>A p.A1018D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, varscan2
- ADARB2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ADGRG4 | c.1830G>T p.Q610H | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ADGRG4 | c.4075A>T p.S1359C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ADGRG4 | c.6575C>A p.S2192* | Nonsense Mutation (SNP) | VAF 37/245 reads (15%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3898G>T p.A1300S (on ENST00000370717 / NM_001366005.1; = p.A1244S on NM_012302.4) | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ADK | c.364G>A p.E122K (on ENST00000286621; = p.E105K on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/381 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AFF4 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- AKR1D1 | c.256_257insT p.G86Vfs*35 | Frame Shift Ins (INS) | VAF 31/237 reads (13%) | called by mutect2, pindel, varscan2
- ALAS2 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALOX15 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ALPK2 | c.1621G>T p.G541* | Nonsense Mutation (SNP) | VAF 37/257 reads (14%) | called by muse, mutect2, varscan2
- ALPK3 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- AMDHD1 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- AMELX | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.096); called by muse, mutect2
- AMER1 | c.3298A>T p.T1100S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- AMER1 | c.2975C>G p.A992G | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AMER1 | c.2062A>T p.T688S | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ANK2 | c.9406C>A p.Q3136K | Missense Mutation (SNP) | VAF 75/481 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ANKRD13B | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD26 | c.2238T>G p.C746W | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ANKRD31 | c.4888G>C p.G1630R | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ANKRD44 | c.2684C>G p.A895G | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.068); called by muse, varscan2
- ANO5 | c.1406G>C p.W469S | Missense Mutation (SNP) | VAF 60/481 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ANTXR1 | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 70/569 reads (12%) | called by muse, mutect2, varscan2
- AP002512.3 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AP5B1 | c.1589G>T p.R530M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- APAF1 | c.3179C>G p.S1060C (on ENST00000551964 / NM_181861.2; = p.S1006C on NM_001160.3) | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- APOL5 | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); called by muse, varscan2
- ARHGAP17 | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, varscan2
- ARHGAP24 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ARHGEF5 | c.1030A>C p.K344Q | Missense Mutation (SNP) | VAF 87/413 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC3 | c.1199T>A p.I400N | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ART5 | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASB2 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ASH1L | c.966_967insT p.K323* | Frame Shift Ins (INS) | VAF 56/218 reads (26%) | called by mutect2, varscan2
- ASTN1 | c.2708G>T p.R903I | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ASTN2 | c.1272C>A p.S424R (on ENST00000313400 / NM_001365069.1; = p.S373R on NM_014010.5) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ASXL3 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2
- ASXL3 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ASXL3 | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATP1A2 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 118/431 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATXN2L | c.1091_1097del p.V364Afs*51 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- AVPR1A | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- B3GAT1 | c.348C>A p.H116Q | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GLCT | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 44/332 reads (13%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by mutect2, varscan2
- BABAM2 | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BAHCC1 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, varscan2
- BDH1 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- BOD1L1 | c.2057G>T p.C686F | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by mutect2, varscan2
- BPIFB4 | c.948C>A p.D316E | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); called by muse, mutect2
- BPTF | c.8355G>T p.Q2785H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2
- BRD8 | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- BRINP3 | c.332T>A p.I111K | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BRWD1 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2
- BRWD3 | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- BTBD17 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- C11orf68 | c.229G>T p.G77C (on ENST00000530188; = p.G118C on NM_031450.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C16orf70 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- C17orf80 | c.583A>T p.N195Y | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- C1QTNF1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- C1orf87 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- C4orf46 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C9orf85 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2
- CACNA1E | c.1616C>A p.S539* | Nonsense Mutation (SNP) | VAF 21/200 reads (11%) | called by muse, mutect2, varscan2
- CALB2 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CAPN1 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CAPN14 | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN6 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, mutect2
- CAPN6 | c.1382A>T p.Y461F | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPRIN1 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CCDC141 | c.3382C>A p.P1128T | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.182); called by muse, mutect2
- CCDC188 | c.1144T>A p.W382R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CCIN | c.34A>T p.S12C | Missense Mutation (SNP) | VAF 35/380 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- CCM2 | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- CCR3 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CD6 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDCA2 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDH18 | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH2 | c.1956G>T p.W652C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH26 | c.126+1G>T p.X42_splice | Splice Site (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- CDH6 | c.663G>T p.L221F | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CDH7 | c.920T>G p.L307W | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2
- CDH7 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2
- CEACAM18 | c.580A>T p.R194W | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, varscan2
- CELSR2 | c.4046del p.G1349Afs*19 | Frame Shift Del (DEL) | VAF 20/162 reads (12%) | called by mutect2, pindel, varscan2
- CENPI | c.1480C>A p.L494I | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.058); called by muse, mutect2
- CER1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 28/202 reads (14%) | called by muse, mutect2, varscan2
- CERS6 | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CFAP20DC | c.1135+1G>C p.X379_splice (on ENST00000482387 / NM_001351530.2; = p.X254_splice on NM_198463.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 33/302 reads (11%) | called by muse, mutect2, varscan2
- CFAP46 | c.2805G>T p.E935D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- CFAP47 | c.6847C>A p.Q2283K | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CHCHD3 | c.525-1G>T p.X175_splice | Splice Site (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2
- CHGB | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, mutect2
- CHM | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.442); called by muse, mutect2
- CHST6 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CLCA1 | c.899T>A p.L300Q | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CLEC1B | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLMN | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- CNKSR2 | c.2336C>G p.S779* | Nonsense Mutation (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- CNOT1 | c.1466T>A p.L489Q | Missense Mutation (SNP) | VAF 66/407 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN1 | c.1550C>G p.T517R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CNTNAP3 | c.2977G>T p.G993W | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP4 | c.1703G>T p.W568L | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP5 | c.3603C>G p.F1201L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COG4 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- COL11A1 | c.1662G>C p.E554D | Missense Mutation (SNP) | VAF 60/466 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL24A1 | c.2228C>A p.P743Q | Missense Mutation (SNP) | VAF 68/438 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL25A1 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL3A1 | c.1559C>A p.A520D | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- COL3A1 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 67/464 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A1 | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- COL6A5 | c.2764G>T p.V922F | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL6A5 | c.5426G>T p.G1809V (on ENST00000312481; = p.G1805V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- COL9A1 | c.2386G>T p.G796C | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORIN | c.2622T>A p.F874L | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPA6 | c.433-2A>T p.X145_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- CPED1 | c.3016C>G p.P1006A | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREB3L3 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CROCC2 | c.2776C>A p.L926M | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, varscan2
- CROCC2 | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- CSDC2 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CSMD3 | c.9825del p.N3276Mfs*48 (on ENST00000297405 / NM_001363185.1; = p.N3107Mfs*48 on NM_052900.3) | Frame Shift Del (DEL) | VAF 34/336 reads (10%) | called by mutect2, pindel, varscan2
- CSMD3 | c.2983G>T p.G995C (on ENST00000297405 / NM_001363185.1; = p.G891C on NM_052900.3) | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUBN | c.8914G>T p.A2972S | Missense Mutation (SNP) | VAF 75/556 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CXCL9 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.494); called by muse, mutect2
- CYLC1 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CYP27C1 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CYP27C1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CYP4F8 | c.710A>T p.N237I | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.148); called by mutect2, varscan2
- DACT1 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DCDC1 | c.2804C>A p.P935H (on ENST00000597505 / NM_001367979.1; = p.P42H on NM_020869.3) | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- DCLRE1B | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- DDX46 | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by muse, mutect2
- DDX5 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIP2C | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMD | c.8230G>C p.E2744Q | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- DMD | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- DNAAF4 | c.875G>T p.W292L | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH10 | c.8912C>A p.P2971Q (on ENST00000409039; = p.P2910Q on NM_207437.3) | Missense Mutation (SNP) | VAF 52/447 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- DNAH10 | c.10217G>T p.R3406L (on ENST00000409039; = p.R3345L on NM_207437.3) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- DOP1A | c.6310C>G p.R2104G | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DPEP3 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- DPYSL5 | c.1529C>A p.P510Q | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DRC1 | c.461G>T p.W154L | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DTX1 | c.1003+1G>T p.X335_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- DUXA | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- DYNAP | c.578del p.T193Kfs*10 (on ENST00000321600; = p.T167Kfs*10 on NM_173629.3) | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- DYSF | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- DYSF | c.1397+1G>T p.X466_splice | Splice Site (SNP) | VAF 57/346 reads (16%) | called by muse, mutect2, varscan2
- DYSF | c.5199A>T p.I1733= | Splice Region (SNP) | VAF 40/242 reads (17%) | called by muse, mutect2, varscan2
- EFL1 | c.2653G>T p.E885* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- EGF | c.3586G>T p.A1196S | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EGFL6 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.392); called by muse, mutect2
- EGFL7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ELAPOR1 | c.801A>C p.T267= | Splice Region (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- EN1 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENAM | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- ENOSF1 | c.686A>T p.Q229L (on ENST00000340116 / NM_001354066.2; = p.Q181L on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EPHA5 | c.1214G>T p.C405F | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- EPHB6 | c.38T>A p.V13E | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- EPS8L3 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERN2 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2
- ESYT2 | c.2075G>T p.G692V (on ENST00000613624; = p.G616V on NM_020728.3) | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC4 | c.1308G>T p.R436S | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- EXOSC9 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.145); called by muse, mutect2
- F8 | c.4457C>G p.T1486R | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); called by muse, mutect2
- FAM13C | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FAM170B | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FAM180A | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- FAM184B | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM189A1 | c.1025T>A p.L342H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM199X | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.893); called by muse, mutect2
- FAM205A | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM227B | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM47A | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- FAM83B | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FAM90A10P | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by mutect2, varscan2
- FAM95C | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- FAT4 | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- FAT4 | c.6266T>C p.L2089P | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBN3 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBRSL1 | c.2719G>C p.A907P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBXO43 | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- FCN1 | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- FHDC1 | c.305G>C p.W102S | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FKBP10 | c.1034del p.P345Rfs*20 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | called by mutect2, pindel, varscan2
- FLACC1 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLG2 | c.2178dup p.G727Rfs*36 | Frame Shift Ins (INS) | VAF 106/589 reads (18%) | called by mutect2, pindel, varscan2
- FLNA | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2
- FLT1 | c.1969+4A>T | Splice Region (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- FMO3 | c.1505T>A p.V502D | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FN1 | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FNDC3B | c.2005A>T p.I669F | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FREM2 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- FRY | c.4427A>T p.K1476I | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.2512A>C p.K838Q | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- FSIP2 | c.15713C>A p.P5238Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- FTCD | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- FUNDC2 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.01); called by muse, mutect2
- FZR1 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- G6PC2 | c.607A>G p.S203G | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABPA | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 42/385 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA3 | c.1132C>A p.L378M | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- GABRA3 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GABRA4 | c.86+1G>T p.X29_splice | Splice Site (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- GALNT8 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT9 | c.1636C>G p.P546A (on ENST00000328957 / NM_001122636.2; = p.P180A on NM_021808.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GARNL3 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- GATA3 | c.799G>C p.G267R | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCLM | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GCN1 | c.2644G>C p.D882H | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GH2 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 67/404 reads (17%) | called by muse, mutect2, varscan2
- GIMAP7 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- GIT1 | c.641_657del p.E214Gfs*2 | Frame Shift Del (DEL) | VAF 16/178 reads (9%) | called by mutect2, pindel
- GJB4 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA12 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GOLGA6L10 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 84/2168 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- GPR101 | c.1008G>C p.K336N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.067); called by muse, mutect2
- GPR152 | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- GPR158 | c.2319C>A p.D773E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GRIA3 | c.2054G>A p.G685D | Missense Mutation (SNP) | VAF 22/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIK4 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- GRIN2A | c.1322A>G p.K441R | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2D | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- GRIP2 | c.502G>T p.G168* (on ENST00000619221; = p.G71* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- GRM4 | c.231C>A p.H77Q | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRM5 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C1 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- GUCY1A2 | c.1795C>A p.L599I | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GYS2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HAGHL | c.499-2A>T p.X167_splice | Splice Site (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- HBG2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 48/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HCN4 | c.1085del p.R362Pfs*46 | Frame Shift Del (DEL) | VAF 38/202 reads (19%) | called by mutect2, pindel*, varscan2
- HDAC6 | c.3434G>C p.C1145S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HDAC9 | c.6C>A p.H2Q | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- HDAC9 | c.1791G>T p.M597I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- HEATR1 | c.5059G>T p.D1687Y | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HECW1 | c.3036G>T p.M1012I | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HERC2 | c.12889G>T p.A4297S | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- HGSNAT | c.1543-1G>T p.X515_splice | Splice Site (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- HMCN1 | c.12703G>T p.G4235C | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPU | c.1939G>T p.G647C (on ENST00000283179; = p.G709C on NM_004501.3) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HRC | c.336dup p.V113Sfs*4 | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | called by pindel, varscan2
- HS1BP3 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HTR3A | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- HTR3A | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HTRA3 | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- HTT | c.7732G>C p.D2578H | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HUWE1 | c.5966A>T p.Q1989L | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- HYDIN | c.12340C>A p.Q4114K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IARS2 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ICAM5 | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- IDO2 | c.224A>T p.K75M (on ENST00000389060; = p.K88M on NM_194294.2) | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- IFI27L1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by mutect2, varscan2
- IFNA1 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- IGF2BP1 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2BP3 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- IGFBP3 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- IGHD3-10 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.565); called by muse, mutect2
- IL13RA2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- IL18RAP | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.911+1G>C p.X304_splice | Splice Site (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
- IL2RB | c.1585del p.L529Cfs*3 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- IL3RA | c.806C>G p.T269R | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- IL9R | c.369C>G p.H123Q | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.269); called by muse, mutect2
- INSC | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- INSM2 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- IPO8 | c.833G>T p.S278I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- IQGAP1 | c.1488-1G>T p.X496_splice | Splice Site (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- IRAK1 | c.2106G>T p.Q702H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2
- ITGA10 | c.1049T>C p.L350P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA2B | c.412T>G p.C138G | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGAD | c.3129G>T p.K1043N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ITGAM | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ITIH5 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IZUMO3 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.09); called by muse, mutect2
- JPH2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT6A | c.3851G>T p.R1284M | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KATNIP | c.1693del p.D565Tfs*26 | Frame Shift Del (DEL) | VAF 21/193 reads (11%) | called by pindel, varscan2
- KCNAB1 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); called by muse, mutect2
- KCNG2 | c.1344C>A p.D448E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK10 | c.1590C>G p.N530K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- KCNK12 | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- KCNQ3 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KCNT2 | c.2781+1G>T p.X927_splice | Splice Site (SNP) | VAF 28/208 reads (13%) | called by muse, mutect2, varscan2
- KCNU1 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 25/291 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.355); called by muse, mutect2
- KCP | c.122A>C p.H41P | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0100 | c.5831A>T p.K1944M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- KIAA1210 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); called by muse, varscan2
- KIAA1549L | c.3221T>A p.L1074Q (on ENST00000321505; = p.L1371Q on NM_012194.3) | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KIAA2012 | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KLHL13 | c.1310G>T p.S437I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- KLK15 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KRT16 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT16 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KRT20 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- KRT26 | c.469A>T p.S157C | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- LAMB3 | c.1802G>T p.R601I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- LAPTM4B | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LARP7 | c.1303A>T p.R435W | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2
- LCE3A | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.58); called by muse, varscan2
- LCT | c.1403G>T p.S468I | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- LDB2 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LENG1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LGALS3BP | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- LIG1 | c.2440-4G>T | Splice Region (SNP) | VAF 44/267 reads (16%) | called by muse, mutect2, varscan2
- LILRB4 | c.1239C>A p.Y413* (on ENST00000391733 / NM_001278428.3; = p.Y412* on NM_001278426.3) | Nonsense Mutation (SNP) | VAF 30/184 reads (16%) | called by muse, varscan2
- LINGO1 | c.1236T>A p.D412E | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIPI | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMAN2L | c.167C>G p.S56W | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXHD1 | c.2017C>A p.L673I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LRP2 | c.4838A>G p.Y1613C | Missense Mutation (SNP) | VAF 62/524 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC4C | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4C | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2
- LRRC63 | c.153G>C p.M51I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by mutect2, varscan2
- LRRN3 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LRRTM4 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- LTBP1 | c.2125G>T p.A709S (on ENST00000404816 / NM_206943.4; = p.A383S on NM_000627.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- LUZP4 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- LUZP4 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.728); called by muse, mutect2
- MAGEB18 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- MAGED2 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, varscan2
- MAN1A1 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- MAP10 | c.701_702del p.G234Efs*74 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.1360C>G p.P454A | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MAPK4 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MATN4 | c.1420G>T p.E474* (on ENST00000372754; = p.E433* on NM_003833.4) | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- MCM2 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MECOM | c.400G>T p.E134* (on ENST00000468789 / NM_001105078.4; = p.E322* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- MED12 | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); called by muse, mutect2
- MGAM2 | c.5137G>A p.D1713N | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MID1 | c.1827C>A p.D609E | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MID2 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- MIDEAS | c.2602G>T p.V868L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MKI67 | c.8575G>T p.G2859C | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MLLT10 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- MLLT6 | c.192G>T p.R64S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MN1 | c.2255G>C p.G752A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPDZ | c.3856G>A p.E1286K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- MRI1 | c.909G>T p.Q303H (on ENST00000040663 / NM_001031727.4; = p.Q256H on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRPL38 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MS4A12 | c.358T>A p.L120I | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.262); called by muse, mutect2
- MS4A18 | c.50C>A p.P17Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MS4A18 | c.577G>T p.G193* (on ENST00000398983; = p.G195* on NM_001354471.1) | Nonsense Mutation (SNP) | VAF 40/246 reads (16%) | called by muse, mutect2, varscan2
- MSANTD4 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MSN | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2
- MTUS1 | c.1757A>T p.Q586L | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MUC16 | c.26950C>G p.P8984A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MUC16 | c.18330G>T p.R6110S | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MUC16 | c.13197G>T p.Q4399H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MYH1 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 44/446 reads (10%) | called by muse, mutect2
- MYH1 | c.2594A>T p.E865V | Missense Mutation (SNP) | VAF 45/448 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- MYH2 | c.4902G>C p.Q1634H | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MYO1A | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MYO7B | c.5556C>A p.S1852R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM3 | c.3259G>T p.A1087S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NARS2 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NAV2 | c.2122G>T p.G708W (on ENST00000396087 / NM_001244963.2; = p.G685W on NM_145117.5) | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NBAS | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 86/373 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- NBEAL1 | c.2257G>T p.G753* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- NELFCD | c.1564G>T p.V522F (on ENST00000602795; = p.V504F on NM_198976.4) | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- NF1 | c.5834G>T p.C1945F (on ENST00000358273 / NM_001042492.3; = p.C1924F on NM_000267.3) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- NIBAN3 | c.1590G>T p.W530C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NLRC3 | c.2567A>G p.H856R | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRC3 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NLRP10 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- NLRP12 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NLRP2 | c.2527C>A p.Q843K | Missense Mutation (SNP) | VAF 44/467 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.223); called by muse, mutect2
- NLRP4 | c.1655C>G p.A552G | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- NLRX1 | c.229+1G>T p.X77_splice | Splice Site (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- NOG | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- NOS1AP | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NOS2 | c.1664G>T p.W555L | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NPFFR2 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.088); called by muse, mutect2
- NPHP3 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NPIPA5 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 28/646 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- NPIPA5 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 29/650 reads (4%) | called by muse, mutect2
- NPR3 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- NPTXR | c.1156T>A p.W386R | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- NR3C2 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR4A2 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 71/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRXN1 | c.1406T>A p.V469E | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- NRXN2 | c.3876G>T p.Q1292H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- NRXN2 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.379); called by muse, mutect2
- NSDHL | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- NTM | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- NUDT9 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OCSTAMP | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- OPRK1 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR10G7 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR13C2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 37/319 reads (12%) | called by muse, mutect2, varscan2
- OR13J1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by mutect2, varscan2
- OR13J1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- OR1S2 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR2AG2 | c.592A>C p.I198L | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2M4 | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | called by muse, varscan2
- OR4A5 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OR4C6 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OR51V1 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52K2 | c.243del p.M83Cfs*12 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | called by mutect2, varscan2
- OR56A3 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 89/527 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- OR5H1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, varscan2
- OR5H15 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR6N1 | c.715T>G p.S239A | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- OR6N2 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR7A5 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.33); called by muse, mutect2
- OR8B12 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8D4 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR8H2 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR9Q1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- OSBP | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OSBPL7 | c.2134G>T p.G712* | Nonsense Mutation (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- OSBPL8 | c.1720C>T p.H574Y | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OTOF | c.3248C>A p.A1083D (on ENST00000272371 / NM_194248.3; = p.A336D on NM_004802.4) | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OTOG | c.3482T>A p.L1161Q | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OVCH2 | c.927C>A p.A309= | Splice Region (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- OXSR1 | c.575G>C p.W192S | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP8 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2
- PCDHGA6 | c.845T>A p.V282E | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCLO | c.8803G>C p.G2935R | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PDE2A | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PDE3A | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PDZD7 | c.2407C>A p.P803T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by mutect2, varscan2
- PDZD8 | c.1642G>T p.G548* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2
- PDZRN3 | c.3047A>T p.N1016I | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2
- PEG3 | c.4115A>T p.Q1372L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PEG3 | c.3364C>A p.L1122I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PFKFB4 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 23/148 reads (16%) | PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- PGLYRP3 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGM2L1 | c.865_888del p.P289_P296del | In Frame Del (DEL) | VAF 30/253 reads (12%) | called by mutect2, pindel
- PHRF1 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, varscan2
- PIK3C2G | c.3522C>A p.D1174E (on ENST00000676171; = p.D1133E on NM_004570.5) | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3R2 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIK3R4 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- PIKFYVE | c.3872G>T p.C1291F | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PKP3 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PLCB4 | c.2512C>G p.P838A | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PLCG2 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.74); called by muse, varscan2
- PLXNA2 | c.3831G>T p.Q1277H | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNA3 | c.3142C>A p.L1048M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLK | c.7A>T p.S3C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- POSTN | c.297C>A p.D99E | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPARD | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1CB | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP1R3A | c.1705C>A p.H569N | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAG1 | c.866G>T p.W289L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by mutect2, varscan2
- PRAMEF10 | c.968A>T p.K323M | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM9 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRKCG | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKCH | c.2029G>T p.V677L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PRODH2 | c.1196C>A p.P399H (on ENST00000301175; = p.P323H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRPF40A | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2
- PRSS45P | c.58G>T p.G20* | Nonsense Mutation (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- PRUNE2 | c.4928G>T p.G1643V | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PSMA8 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2
- PTH2 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.521); called by muse, varscan2
- PTPRC | c.3511dup p.X1171_splice | Splice Site (INS) | VAF 32/352 reads (9%) | called by mutect2*, pindel
- PTPRZ1 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
597 further variants in this file (200 protein-altering or splice-affecting, 248 silent, 149 other) are not listed here.
